MMRF case MMRF_2501 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/21a0cabb-c588-4a2c-bd54-8a3047a3a077

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.7 years (20,333 days); ISS stage: II; Days to last known disease status: 703 days (1.9 years); Days to last follow up: 703 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 172 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 276 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.068 mg/dL; Immunoglobulin G 34.5 g/L; Immunoglobulin A 0.185 g/L; Immunoglobulin M 0.171 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 32 g/L; Total Protein 10 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 32.9 mg/dL.
- Day 85 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.544 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.557 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 0.304 g/L; Immunoglobulin M 0.411 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 7.4 g/dL; Glucose 6.93 mmol/L.
- Day 191 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.753 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.404 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 33 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.58 mmol/L; Albumin 38 g/L; Total Protein 8.3 g/dL; Glucose 7.15 mmol/L.
- Day 269 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.992 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.386 g/L; Immunoglobulin M 0.216 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 352 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.367 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.89 mmol/L.
- Day 434 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.462 g/L; Immunoglobulin M 0.333 g/L; Hemoglobin 8 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.71 mmol/L.
- Day 528 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.914 g/L; Immunoglobulin M 0.412 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 6.16 mmol/L.
- Day 647 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.896 g/L; Immunoglobulin M 0.443 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.06 mmol/L.
- Day 703 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.901 g/L; Immunoglobulin M 0.528 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 7.26 mmol/L.

Other clinical attributes
- Day -6: Weight: 102 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2501_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2501_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
